Somatic mutation profile of tumor specimen TCGA-2L-AAQJ-01A (aliquot TCGA-2L-AAQJ-01A-12D-A397-08) from TCGA case TCGA-2L-AAQJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.6 years (18,103 days).
Specimen TCGA-2L-AAQJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aaff7f9-0312-4a17-9293-3bcf7da1c287.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2L-AAQJ-11A (Solid Tissue Normal), aliquot TCGA-2L-AAQJ-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef342ede-d759-4c21-b92b-8b52e57726cb

The open-access MAF lists 95 somatic variants for this specimen: 77 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 14, Nonsense Mutation 6, Frame Shift Ins 4, Intron 2, Frame Shift Del 2, 3'UTR 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 61/267 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS15 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 117/510 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs200241034, COSV100143763; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4943G>A p.R1648Q | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762449626, COSV54444754; called by muse, mutect2, varscan2
- ADARB1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs142476560, COSV100654113; called by muse, mutect2, varscan2
- AKAP6 | c.4954C>T p.R1652* | Nonsense Mutation (SNP) | VAF 56/279 reads (20%) | catalogued as COSV99804178; called by muse, mutect2, varscan2
- AMZ2 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 67/525 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV100703221; called by muse, mutect2, varscan2
- ARHGAP36 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 124/711 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99358186; called by muse, mutect2, varscan2
- ARHGAP5 | c.4242G>A p.W1414* (on ENST00000345122 / NM_001030055.2; = p.W1413* on NM_001173.3) | Nonsense Mutation (SNP) | VAF 95/408 reads (23%) | catalogued as COSV53735279; called by muse, mutect2, varscan2
- BAHCC1 | c.2717G>A p.G906D | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs553180909, COSV100312021; called by muse, mutect2, varscan2
- BCAN | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 97/593 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs770559603, COSV100228462, COSV61257115; called by muse, mutect2, varscan2
- BTBD11 | c.3254G>T p.R1085M (on ENST00000280758 / NM_001018072.2; = p.R622M on NM_001017523.2) | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV99776909; called by muse, mutect2, varscan2
- CACNA1D | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99859880; called by muse, mutect2, varscan2
- CAND1 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 90/396 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101598288; called by muse, mutect2, varscan2
- CDKN2A | c.52_57dup p.T18_A19dup | In Frame Ins (INS) | VAF 30/134 reads (22%) | catalogued as rs1563892769, COSV58718839; ClinVar: uncertain significance; called by mutect2, varscan2
- CECR2 | c.2117C>T p.T706I (on ENST00000342247 / NM_001290047.2; = p.T523I on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99379010; called by muse, mutect2
- CEP135 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 44/247 reads (18%) | catalogued as COSV99954862; called by muse, mutect2, varscan2
- COL14A1 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs1318709579, COSV99920539; called by muse, mutect2, varscan2
- DIO3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1267537465, COSV100832258; called by muse, mutect2, varscan2
- DLGAP1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV59800338; called by muse, mutect2, varscan2
- DNASE1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs140530129, COSV99892680; called by muse, mutect2, varscan2
- DOCK4 | c.5723G>A p.R1908Q | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.921); catalogued as rs374504389; called by muse, mutect2, varscan2
- ENTPD2 | c.877T>A p.F293I | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100445884; called by muse, varscan2
- ENTPD4 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 105/582 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs1443218958, COSV100652777; called by muse, mutect2, varscan2
- FAM47A | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.461); catalogued as rs1477454448, COSV60498040; called by muse, mutect2, varscan2
- FAM71B | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs752153945, COSV57228020; called by muse, mutect2, varscan2
- FREM2 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs755744742, COSV54831109; called by muse, mutect2, varscan2
- FSCN1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV61019204; called by muse, mutect2, varscan2
- GLB1L | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 104/535 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1559262200, COSV99850858; called by muse, mutect2, varscan2
- GPI | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 165/854 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs756159470, COSV100731572; called by muse, mutect2, varscan2
- GPR142 | c.4A>T p.S2C | Missense Mutation (SNP) | VAF 56/415 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV100171004; called by muse, mutect2, varscan2
- GUCD1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV101238140; called by muse, mutect2, varscan2
- IRAK3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99706450; called by muse, mutect2, varscan2
- ITSN2 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 127/1033 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as rs550046461, COSV100744116; called by muse, mutect2, varscan2
- JCAD | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs746067055, COSV64761252; called by muse, mutect2, varscan2
- KCND1 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs145016539, COSV54412357, COSV99502004; called by muse, mutect2, varscan2
- LDB2 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 135/677 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as rs773576293, COSV58776580, COSV58778036; called by muse, mutect2, varscan2
- LPCAT3 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.375); catalogued as COSV99781289; called by muse, mutect2, varscan2
- MAGI2 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.766); catalogued as rs759667457, COSV62678117; called by muse, mutect2, varscan2
- MAP3K21 | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1229276980, COSV64041157; called by muse, mutect2, varscan2
- MYO3A | c.2428G>A p.G810S | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.155); catalogued as COSV99781410; called by muse, mutect2, varscan2
- NR0B1 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100973586; called by muse, mutect2, varscan2
- NR0B1 | c.415C>G p.H139D | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100973587; called by muse, mutect2, varscan2
- OGDH | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 76/514 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99759559; called by muse, mutect2, varscan2
- OR51I1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs115148889, COSV66507890; called by muse, mutect2, varscan2
- OXTR | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs200966415; called by muse, mutect2, varscan2
- PAG1 | c.1102A>C p.T368P | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99597878; called by muse, mutect2, varscan2
- PDHA2 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54778469; called by muse, mutect2, varscan2
- PGC | c.1111T>C p.Y371H | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026454; called by muse, mutect2
- PIK3R5 | c.1115C>G p.S372W | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV99353809; called by muse, mutect2, varscan2
- PLCE1 | c.958del p.E320Sfs*6 | Frame Shift Del (DEL) | VAF 56/442 reads (13%) | catalogued as COSV53374925; called by mutect2, pindel, varscan2
- PLEKHG2 | c.3098C>G p.S1033* | Nonsense Mutation (SNP) | VAF 71/370 reads (19%) | catalogued as COSV99217486, COSV99218031; called by muse, mutect2, varscan2
- PM20D1 | c.61A>C p.T21P | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100900242; called by muse, mutect2, varscan2
- PSG6 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 219/921 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs750179815, COSV51834910; called by muse, mutect2, varscan2
- PTPRN2 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 140/692 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs142388788; called by muse, mutect2, varscan2
- SACS | c.5919A>C p.K1973N | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV101207707; called by muse, mutect2, varscan2
- SETBP1 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.207); catalogued as rs367742803, COSV99954793; called by muse, mutect2, varscan2
- SH2D3C | c.1117C>T p.R373C (on ENST00000314830 / NM_170600.3; = p.R216C on NM_005489.4) | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1367072826, COSV59119441; called by muse, mutect2, varscan2
- SIAH3 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101248035; called by muse, mutect2, varscan2
- SIGLEC1 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs753045959, COSV52465738; called by muse, mutect2, varscan2
- STK32A | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 75/402 reads (19%) | catalogued as COSV100097678; called by muse, mutect2, varscan2
- TENM2 | c.1367G>A p.R456Q (on ENST00000518659 / NM_001122679.2; = p.R224Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs778257205, COSV101319393; called by muse, mutect2, varscan2
- TGFBR2 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 52/213 reads (24%) | catalogued as COSV55443267; called by muse, mutect2, varscan2
- TGM5 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 65/576 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs763398483, COSV55008875; called by muse, mutect2, varscan2
- TIAF1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs151013388; called by muse, mutect2, varscan2
- TNN | c.3377G>T p.W1126L | Missense Mutation (SNP) | VAF 122/566 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53435823, COSV99512880; called by muse, mutect2, varscan2
- TRPV4 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as rs372583866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP35 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs1320446798, COSV101489134; called by muse, mutect2, varscan2
- VSIG1 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 206/1280 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99480454; called by muse, mutect2, varscan2
- VWF | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 82/348 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs181452677, COSV54610591; called by muse, mutect2, varscan2
- WIPI2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 109/553 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs200762936, COSV56592153; called by muse, mutect2, varscan2
- ZNF423 | c.2003G>A p.R668Q (on ENST00000563137 / NM_001379286.1; = p.R660Q on NM_015069.4) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.205); catalogued as rs200218868, COSV52202105, COSV99283618; called by muse, mutect2, varscan2
- ZNF835 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs763139627, COSV73379258; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676dup p.E893* | Frame Shift Ins (INS) | VAF 77/363 reads (21%) | called by mutect2, varscan2
- GAS7 | c.209_210insT p.E72Rfs*31 (on ENST00000432992 / NM_201433.2; = p.E12Rfs*31 on NM_201432.2) | Frame Shift Ins (INS) | VAF 72/222 reads (32%) | called by mutect2, pindel*, varscan2
- PRIMPOL | c.939dup p.P314Sfs*9 | Frame Shift Ins (INS) | VAF 18/180 reads (10%) | called by mutect2, pindel
- SETD1A | c.2364_2365del p.G789Hfs*35 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | called by mutect2, pindel, varscan2
- ZNF141 | c.1162dup p.I388Nfs*11 | Frame Shift Ins (INS) | VAF 48/291 reads (16%) | called by mutect2, varscan2
- ADCY5 | c.2646G>A p.A882= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as rs148384901; called by muse, mutect2, varscan2
- DOCK5 | c.2323T>C p.L775= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs200618924, COSV99377772; called by muse, mutect2, varscan2
- FPR2 | c.795C>T p.T265= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as rs892908435, COSV100389440; called by muse, mutect2, varscan2
- GLI3 | c.3372C>T p.H1124= | Silent (SNP) | VAF 101/482 reads (21%) | catalogued as rs542238121, COSV67886267; called by muse, mutect2, varscan2
- HDX | c.366A>T p.T122= | Silent (SNP) | VAF 68/454 reads (15%) | catalogued as COSV99947993; called by muse, mutect2, varscan2
- KIF26A | c.300C>A p.L100= | Silent (SNP) | VAF 64/254 reads (25%) | catalogued as rs1440026691, COSV100181531; called by muse, mutect2, varscan2
- LRRC8A | c.441G>A p.P147= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs745404515, COSV52188381; called by muse, mutect2, varscan2
- NAA11 | c.501C>T p.G167= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV54516149; called by muse, mutect2, varscan2
- PDE2A | c.1383C>T p.A461= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as rs1385539455, COSV57806930; called by muse, mutect2, varscan2
- PTPRS | c.1194C>T p.Y398= | Silent (SNP) | VAF 67/284 reads (24%) | catalogued as rs144956737; called by muse, mutect2, varscan2
- RBM12 | c.2349G>A p.S783= | Silent (SNP) | VAF 80/334 reads (24%) | catalogued as rs943635481, COSV100468040; called by muse, mutect2, varscan2
- SDK1 | c.4509C>T p.S1503= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs748912663, COSV101269711, COSV67386750; called by muse, mutect2
- TCERG1 | c.2889A>G p.Q963= | Silent (SNP) | VAF 74/368 reads (20%) | catalogued as COSV99695250; called by muse, mutect2, varscan2
- TUBB8 | c.1248C>T p.N416= | Silent (SNP) | VAF 13/360 reads (4%) | catalogued as rs782002737; called by muse, mutect2
- DOT1L | c.4606+1053G>A | Intron (SNP) | VAF 29/146 reads (20%) | catalogued as COSV58536926; called by muse, mutect2, varscan2
- DPP6 | c.*213C>T | 3'UTR (SNP) | VAF 17/78 reads (22%) | catalogued as rs1239710952, COSV59645853; called by muse, mutect2, varscan2
- MIR509-1 | n.82T>A | RNA (SNP) | VAF 170/975 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31438G>A | Intron (SNP) | VAF 52/218 reads (24%) | catalogued as rs780564286, COSV99829457; called by muse, varscan2
